Surgical pathology report (de-identified scan), TCGA case TCGA-CN-4736, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-CN-4736-01A (Primary Tumor).

[page 1 of 4]
PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Squamous cell cancer right tongue
PROCEDURE: Partial glossectomy
SPECIFIC CLINICAL QUESTION: Yes, squamous cell carcinoma
OUTSIDE TISSUE DIAGNOSIS: No
PRIOR MALIGNANCY: No
CHEMOTHERAPY: No
ORGAN TRANSPLANT: No
IMMUNOSUPPRESSION: No
OTHER DISEASES: No

FINAL DIAGNOSIS:**PART 1: RIGHT PARTIAL GLOSSECTOMY –**

- A. SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED WITH DEEP INVASION OF LINGUAL MUSCULATURE (1.9 CM) (see comment).
- B. PERINEURAL INVASION IS SEEN.
- C. MARGINS OF RESECTION ARE FREE OF TUMOR.
- D. ALTHOUGH THE DEEP MARGIN OF RESECTION IS TECHNICALLY FREE OF TUMOR, THE TUMOR IS LESS THAN 1 MM FROM THE MARGIN. (SEE PART 2FOR ADDITIONAL MARGINS).
- E. T1 Nx Mx

**PART 2: DORSAL AND DEEP MARGINS, EXCISION -
NO TUMOR SEEN.****COMMENT:**

The tumor is poorly defined grossly and measures approximately 1.9 cm microscopically.

My signature is attestation that I have personally reviewed the submitted material(s) and the final diagnosis reflects that evaluation.

GROSS DESCRIPTION:

The specimen is submitted unfixed in two parts.

[page 2 of 4]
Pathology Report

Part 1 is identified as "right partial glossectomy, stitch anterior" and is labeled with the patient's name and initials [REDACTED]. Received is a 3.0 x 3.5 x 1.5 cm partial glossectomy. Suture marks anterior. The mucosal surface is firm focally ulcerated and pale tan-white. The deep surface is red tan and roughened. On cross-section the cut surface shows a poorly defined firm irregular solid white mass coming to within 0.2 cm of the deep margin. A shave cross section of the ventral margin and radial cross-sections in relation to deep margin are taken for intraoperative frozen section diagnostic evaluation.

Digital imaging photographs are taken.

INK CODE:

Blue - deep
Black - anterior
Red - posterior
Yellow - dorsal
Green - ventral (not true margin)

CASSETTE CODE:

1AFS - frozen section ventral shave margin entirely submitted
1B FS - frozen section radial cross-section in relation to deep
1C - radial cross-section in relation to anterior (at stitch)
1D - radial cross-section in relation to posterior
1E thru 1H - serial cross sections in relation to dorsal margin and re-inked ventral surface

Part 2 is identified as "dorsal and deep margin, stitch anterior" and is labeled with the patient's name and initials [REDACTED]. Received is a 2.0 x 2.0 x 0.8 cm portion of roughened red-tan tissue. Suture marks anterior. Dorsal and deep margins evaluated for intraoperative frozen section diagnosis.

INK CODE:

Blue - anterior margin at stitch

CASSETTE CODE:

2AFS - frozen section tissue dorsal and deep margins totally submitted
2B - remaining tissue anterior
2C - remaining tissue posterior

GROSSED BY: [REDACTED]
[REDACTED]

INTRAOPERATIVE CONSULTATION:

1AFS: RIGHT TONGUE, VENTRAL SHAVE MARGIN (frozen section) -

- A. BENIGN
- B. NO TUMOR SEEN [REDACTED]

1BI S RIGHT TONGUE, DEEP RADIAL MARGIN (frozen section) -

- A. MALIGNANT
- B. SQUAMOUS CELL CARCINOMA
- C. DEEP MARGIN FREE OF TUMOR [REDACTED]

2AFS: RIGHT TONGUE, DORSAL AND DEEP MARGINS (frozen section) -

- A. BENIGN
- B. NO TUMOR SEEN [REDACTED]

[page 3 of 4]
Pathology Report

MICROSCOPIC:

Microscopic examination substantiates the above diagnosis.

The following statement applies to all immunohistochemistry, insitu hybridization (ISH & FISH), molecular anatomic pathology, and immunofluorescence testing:

The testing was developed and its performance characteristics determined by the [REDACTED] Department of Pathology, as required by the [REDACTED] regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use. Tissue fixation ranges from a minimum of 2 to a maximum of 84 hours.

This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] ("CLIA") as qualified to perform high-complexity clinical testing. Pursuant to the requirements of CLIA, ASR's used in this laboratory have been established and verified for accuracy and precision. Additional information about this type of test is available upon request.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY UPPER AERODIGESTIVE TRACT AND SALIVARY GLAND TUMORS

SPECIMEN TYPE:	Resection: Partial Glossectomy
TUMOR SITE:	Oral Cavity
TUMOR SIZE:	Greatest dimension: 1.9 cm
HISTOLOGIC TYPE:	Squamous cell carcinoma, conventional
HISTOLOGIC GRADE:	G2
PATHOLOGIC STAGING (pTNM):	pT1 pNX pMX
MARGINS:	Margins uninvolved by tumor
VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L):	Absent
PERINEURAL INVASION:	Present
ADDITIONAL PATHOLOGIC FINDINGS:	Other: Deep invasion of lingual musculature

HISTO TISSUE SUMMARY/SLIDES REVIEWED:

Part 1: Right Partial Glossectomy

Stain/cnt	Block
H&E x 1	C
H&E x 1	D
H&E x 1	E
H&E x 1	F
H&E x 1	G
H&E x 1	AFS
H&E x 1	BFS

Part 2: Dorsal and Deep Margin

Stain/cnt	Block
H&E x 1	B
H&E x 1	C
H&E x 1	AFS

[page 4 of 4]
Pathology Report

ICD-9 Diagnosis Codes: {None Entered}

TC1

Source: NCI Genomic Data Commons file 823db557-22a0-468f-a5f9-adb1a33c2b21 (TCGA-CN-4736.224E63D4-AF9F-45D7-9430-A6BF55FA7BF8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).